Somatic mutation profile of tumor specimen TCGA-13-1499-01A (aliquot TCGA-13-1499-01A-01W-0549-09) from TCGA case TCGA-13-1499, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.6 years (20,668 days).
Specimen TCGA-13-1499-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3097d354-3c07-4527-9d7e-3639bbcad261.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1499-10A (Blood Derived Normal), aliquot TCGA-13-1499-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e88103e-cd94-400c-b48f-c958afcce95b

The open-access MAF lists 84 somatic variants for this specimen: 61 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 19, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 1, Intron 1, 5'Flank 1, 3'Flank 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 44/106 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- UBR4 | c.4045C>G p.R1349G | Missense Mutation (SNP) | VAF 50/386 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs776593168, COSV64391881, COSV64395742; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs780454385, COSV100068359, COSV57057556; called by muse, mutect2, varscan2
- ABCG4 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs775075804, COSV56645073; called by muse, mutect2, varscan2
- ACTL8 | c.984G>C p.W328C | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as COSV64862248; called by muse, mutect2, varscan2
- AL121899.2 | c.1448C>G p.T483R | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV101198632, COSV67351841; called by muse, mutect2, varscan2
- AREL1 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 186/433 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.085); catalogued as COSV62667537; called by muse, mutect2, varscan2
- ARHGEF1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs1053450616, COSV61529056; called by muse, mutect2, varscan2
- CCDC42 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV53449484; called by muse, mutect2, varscan2
- CKAP2 | c.1742A>G p.N581S (on ENST00000378037 / NM_001098525.2; = p.N580S on NM_018204.5) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV51623788; called by muse, mutect2, varscan2
- CLSPN | c.1366C>G p.L456V | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as rs1460942615, COSV52055182; called by muse, mutect2, varscan2
- DNAJC6 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 93/428 reads (22%) | catalogued as COSV54779399; called by muse, mutect2, varscan2
- DPYSL3 | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs1251865507, COSV100574854; called by muse, mutect2, varscan2
- DSN1 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 55/325 reads (17%) | catalogued as COSV65519840; called by muse, mutect2, varscan2
- ERGIC1 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV100442566; called by muse, mutect2
- FAM135A | c.3523G>A p.D1175N (on ENST00000370479 / NM_001351599.1; = p.D962N on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/407 reads (4%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.995); catalogued as COSV99524964; called by muse, mutect2
- FAM13A | c.2505C>G p.Y835* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99982622; called by muse, varscan2
- FANCC | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs955739738, COSV56664676; called by muse, mutect2
- FANCE | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs1419380182, COSV57690708; called by muse, mutect2, varscan2
- FBN3 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54468174; called by muse, varscan2
- FLT1 | c.1468T>C p.F490L | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV56736803; called by muse, mutect2, varscan2
- H4C8 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0.04); catalogued as COSV56805446, COSV56805600, COSV99175483; called by muse, mutect2, varscan2
- HAS2 | c.1074C>A p.Y358* | Nonsense Mutation (SNP) | VAF 20/536 reads (4%) | catalogued as COSV100391342; called by muse, mutect2
- HSD3B2 | c.1061A>T p.E354V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV65593748; called by muse, mutect2, varscan2
- IPO9 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV64234917; called by muse, mutect2, varscan2
- ITGA6 | c.1570C>A p.Q524K (on ENST00000442250; = p.Q485K on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/453 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV51241416; called by muse, mutect2, varscan2
- KCNA1 | c.234C>A p.N78K | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs1312855741, COSV101230077; called by muse, mutect2
- KCTD3 | c.86T>G p.F29C | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52069253; called by muse, mutect2, varscan2
- MAP4K3 | c.1419A>C p.Q473H | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs769914055, COSV55716364; called by muse, mutect2
- MCCC2 | c.1190C>G p.P397R | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100039707; called by muse, mutect2, varscan2
- MDN1 | c.7298G>T p.G2433V | Missense Mutation (SNP) | VAF 84/603 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV65527140; called by muse, mutect2, varscan2
- NEB | c.6620A>C p.H2207P | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV51442875; called by muse, mutect2, varscan2
- NRBP1 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99274684; called by muse, mutect2
- OR6K3 | c.381G>C p.E127D (on ENST00000368146; = p.E111D on NM_001005327.2) | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63746170; called by muse, mutect2, varscan2
- PADI3 | c.1146A>T p.K382N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV64935011; called by muse, mutect2, varscan2
- PADI4 | c.1073A>T p.Q358L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV64924658; called by muse, mutect2, varscan2
- PDE4DIP | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.413); catalogued as rs587714051, COSV100515689; called by muse, mutect2, varscan2
- PLEKHG4B | c.1234G>T p.V412F (on ENST00000283426; = p.V768F on NM_052909.5) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs534336026, COSV52046756, COSV52052208; called by muse, mutect2, varscan2
- PLXDC1 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV59552890; called by muse, mutect2, varscan2
- PROM1 | c.2043C>A p.H681Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as COSV71699754; called by muse, mutect2, varscan2
- PTPN3 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 69/365 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1237196580, COSV52709091; called by muse, mutect2, varscan2
- SCN3A | c.2902A>G p.M968V | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV51812780; called by muse, mutect2, varscan2
- SH3YL1 | c.641A>G p.Y214C | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62157307; called by muse, mutect2, varscan2
- SHANK2 | c.4204G>T p.D1402Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53611863; called by muse, mutect2, varscan2
- SNRPA | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV54682194, COSV54683177; called by mutect2, varscan2
- SPATA21 | c.1202A>G p.Q401R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59185687; called by muse, mutect2, varscan2
- SUCLG1 | c.365C>A p.P122Q | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101205291; called by muse, mutect2
- TAF1 | c.2215G>C p.E739Q (on ENST00000373790 / NM_138923.4; = p.E760Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV99333991; called by muse, mutect2
- TESPA1 | c.1544C>A p.T515N (on ENST00000316577 / NM_001098815.3; = p.T377N on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/541 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.109); catalogued as COSV57260371; called by muse, mutect2, varscan2
- TIAM2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as COSV59700077; called by muse, mutect2, varscan2
- TNKS2 | c.2002G>C p.D668H | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV65416365; called by muse, mutect2, varscan2
- TRPC1 | c.1573C>T p.P525S (on ENST00000476941 / NM_001251845.2; = p.P491S on NM_003304.4) | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs776357224, COSV56428075; called by muse, mutect2, varscan2
- XRCC6 | c.1254A>C p.E418D | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63753499; called by muse, mutect2, varscan2
- ZFPM2 | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV68289111; called by muse, mutect2, varscan2
- ZNF106 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 119/398 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV55520133; called by muse, mutect2, varscan2
- ZNF780A | c.1770T>G p.C590W | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100574908; called by muse, mutect2
- ARPC3 | c.488_504delinsG p.F163* | Frame Shift Del (DEL) | VAF 37/208 reads (18%) | called by pindel, varscan2*
- CFAP299 | c.632_640del p.R211_T213del | In Frame Del (DEL) | VAF 24/129 reads (19%) | called by mutect2, pindel, varscan2
- HIPK4 | c.211del p.H71Tfs*86 | Frame Shift Del (DEL) | VAF 11/116 reads (9%) | called by mutect2, pindel, varscan2
- SLC30A10 | c.1235_1262del p.Q412Lfs*17 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel
- SLFN12 | c.585dup p.L196Ifs*5 | Frame Shift Ins (INS) | VAF 43/233 reads (18%) | called by mutect2, pindel, varscan2
- CDH10 | c.774G>A p.T258= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as rs188355658; called by muse, mutect2, varscan2
- CEP250 | c.6897C>G p.T2299= | Silent (SNP) | VAF 97/611 reads (16%) | catalogued as COSV61170329, COSV61172610; called by muse, mutect2, varscan2
- DHX29 | c.1296T>C p.D432= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV52420367; called by muse, mutect2, varscan2
- FBN3 | c.2538C>T p.C846= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs754700869, COSV54468160; called by muse, varscan2
- HECW2 | c.2601C>T p.R867= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as COSV53669151; called by muse, mutect2, varscan2
- HMCN1 | c.5730C>T p.H1910= | Silent (SNP) | VAF 60/382 reads (16%) | catalogued as rs748846606, COSV54925721; called by muse, mutect2, varscan2
- MUC7 | c.366A>G p.K122= | Silent (SNP) | VAF 91/472 reads (19%) | catalogued as COSV59219626; called by muse, mutect2, varscan2
- OR5M1 | c.319C>T p.L107= | Silent (SNP) | VAF 46/355 reads (13%) | catalogued as COSV73202320; called by muse, mutect2, varscan2
- PCDHA4 | c.2061G>C p.V687= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV63544555; called by muse, mutect2, varscan2
- PCDHGA5 | c.1404T>G p.G468= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV54001235; called by muse, mutect2, varscan2
- RBM26 | c.1461A>C p.S487= | Silent (SNP) | VAF 114/408 reads (28%) | catalogued as COSV57397852; called by muse, varscan2
- SCN5A | c.2763T>C p.L921= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV61134995; called by muse, mutect2, varscan2
- SLC1A2 | c.366G>T p.V122= | Silent (SNP) | VAF 111/499 reads (22%) | catalogued as COSV53524392; called by muse, mutect2, varscan2
- SPATS1 | c.744T>A p.L248= | Silent (SNP) | VAF 45/239 reads (19%) | catalogued as COSV99912989; called by muse, mutect2, varscan2
- TCEAL8 | c.129C>T p.S43= | Silent (SNP) | VAF 138/439 reads (31%) | catalogued as rs758027703, COSV63506585; called by muse, mutect2, varscan2
- THRAP3 | c.2205T>A p.G735= | Silent (SNP) | VAF 52/290 reads (18%) | catalogued as COSV63569164; called by muse, mutect2, varscan2
- TLL1 | c.543C>T p.A181= | Silent (SNP) | VAF 63/218 reads (29%) | catalogued as rs1443712747, COSV50308811; called by muse, mutect2, varscan2
- ZEB1 | c.3207G>A p.E1069= | Silent (SNP) | VAF 87/234 reads (37%) | catalogued as rs765424726, COSV58042913; called by muse, mutect2, varscan2
- ZNF236 | c.270G>A p.G90= | Silent (SNP) | VAF 46/183 reads (25%) | catalogued as COSV53494219; called by muse, mutect2, varscan2
- C14orf178 | n.567G>T | RNA (SNP) | VAF 12/88 reads (14%) | catalogued as COSV63468527; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446089 G>A | 3'Flank (SNP) | VAF 17/55 reads (31%) | catalogued as rs773211108; called by muse, mutect2, varscan2
- SLC17A3 | c.303+222T>A | Intron (SNP) | VAF 7/38 reads (18%) | catalogued as COSV57759955, COSV57761117; called by muse, mutect2, varscan2
- STMP1 | chr7:135660428 T>A | 5'Flank (SNP) | VAF 58/260 reads (22%) | called by muse, mutect2, varscan2
